Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25T, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25T-01A (Primary Tumor).

[page 1 of 2]
LABORATORY SERVICES

1CD-0-3

carcinoma, hepatocellular, NOS

8170/3

Site: liver c22.0

lv

4/25/11

Accession #:

Name:

Patient ID:

PHN:

ALT ID:

DOB :

Telephone:

Requesting Physician:

Encounter:

Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

ORIGINAL REPORT

SPECIMEN:

A: Right liver and segment 4.

CLINICAL HISTORY:

MRI liver mass 12.0 cm x 8.0 cm (subscapular).

DIAGNOSIS:

A. RIGHT LIVER AND SEGMENT 4:

- HEPATOCELLULAR CARCINOMA.
- GRADE 2, pT3 (TUMOR MEASURES 9.8 CM IN MAXIMUM DIMENSION).
- BENIGN CAVERNOUS HEMANGIOMA.
- BENIGN BILE DUCT HEMATOMA.
- GALLBLADDER AND LYMPH NODE WITHIN NORMAL LIMITS.
- SEE MICROSCOPIC DESCRIPTION.

reported:

Reported by:

Signed by: F

(Electronic Signature)

GROSS DESCRIPTION:

A: The specimen is received fresh and submitted in formalin. The specimen consists of a 1441 g lobe of liver measuring 17.0 x 17.4 x 9.8 cm. The surface of the specimen is smooth with a concave appearing neoplasm infiltrating the surface of the specimen. This area measures 9.8 x 9.0 cm. This is white in appearance and slightly necrotic. Surrounding this neoplasm on the surface is a rim of hemorrhagic area. The specimen is serially sectioned to reveal that this neoplasm is somewhat well circumscribed and measures 13.0 x 11.8 x 8.0 cm. This neoplasm has a homogeneous white/tan appearance. There is some slight central necrosis. This neoplasm comes to within 0.7 cm of the surgical resection margin, which has been painted black. Adjacent to this neoplasm is another well circumscribed white/tan neoplasm measuring 1.4 x 1.2 x 1.2 cm. It is located 1.0 cm from the largest neoplasm and also 1.0 cm from the resection margin. Also identified attached to the surface of the specimen is a fibrous cystic structure measuring 2.0 x 1.4 x 1.2 cm, which is open and contains what appears to be green bile with an inner mucosal surface.

Diagnosis Discrepancy		K
Primary Tumor Site Discrepancy		K
IMPA Discrepancy		K
Prior Malignancy History		K
Dual/Synchronous Primary Notes		K

Printed:

Name:

FINAL

Page 1 *** CONTINUED

[page 2 of 2]
LABORATORY SERVICES

Accession #:

Name:

Patient ID:

PHN:

ALT ID:

DOB:

Telephone:

Requesting Physician:

Encounter:

Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

GROSS DESCRIPTION:

Please note the sections of the tumor and normal portions of liver are taken for Tumor Bank.

Summary of sections:

- A1 to A8 - Representative sections of the neoplasm including closest points of invasion to resection margin and surface of the liver capsule.
- A9 - Representative section of gallbladder. Portion of tissue attached to the liver.
- A10 - Representative section of the smaller above described nodule in closest point of invasion to the resection margin.
- A11 - Representative section of normal-appearing liver parenchyma.

MICROSCOPIC DESCRIPTION:

Sections show infiltrative carcinoma with morphologic features of hepatocellular carcinoma. The overall patterns are a combination of trabecular and pseudoglandular. The nuclei are slightly enlarged and mildly pleomorphic, however, the cells still have abundant cytoplasm. This would correspond to a tumor grade of 2. One large nodule is present measuring 9.8 cm in maximum dimension. The gross appearance would correspond to the diffuse type. The tumor is 0.7 cm from the nearest surgical resection margin. There is moderate fibrosis within the tumor. Angiolymphatic invasion is not identified in these sections. Mitotic rate is 6/10 HPF. The non-malignant liver is unremarkable. One regional lymph node and the gallbladder are also unremarkable.

RESIDENT:

Dr.

Procedure:

FINAL

Source: NCI Genomic Data Commons file 5ced3f4d-5fcd-4c43-9df2-ebb9da06dc8a (TCGA-G3-A25T.BC6447AE-5740-437A-987E-5ECB891667FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).